Gene-level copy-number profile of tumor specimen TCGA-DX-A48O-01A from TCGA case TCGA-DX-A48O, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 64.0 years (23,364 days).
Specimen TCGA-DX-A48O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.caad6d94-41bc-401e-bc6d-8e80a6a0e25e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A48O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf453460-47d5-4b64-a203-f8212b7c95c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,100; copy number 2: 43,294; copy number 3: 2,384; copy number 4: 27; copy number 6: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A48O-01A-11D-A306-01): tumor purity 0.92, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:52,144,349–52,190,638, 4 genes, copy number 6: MIR206, LINCMD1, MIR133B, IL17A.
- chr17:12,020,829–12,143,830, 1 gene, copy number 6 (within-gene range 1–6): MAP2K4.
- chr17:12,081,899–12,790,242, 9 genes, copy number 6: MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1.

Autosomal genes at a single copy (total copy number 1): 14,100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
